Somatic mutation profile of tumor specimen TCGA-55-8096-01A (aliquot TCGA-55-8096-01A-11D-2238-08) from TCGA case TCGA-55-8096, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.6 years (24,684 days).
Specimen TCGA-55-8096-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acda5160-7899-4a50-88ed-418d55adaea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8096-10A (Blood Derived Normal), aliquot TCGA-55-8096-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51371120-76d8-4bd2-857d-2bc06c574ad6

The open-access MAF lists 153 somatic variants for this specimen: 118 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 33, Nonsense Mutation 12, Splice Site 2, Frame Shift Del 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 197/422 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, varscan2
- ADAMTS5 | c.2186C>A p.S729Y | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99538371; called by muse, mutect2, varscan2
- ADGRE1 | c.779C>G p.T260R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.624); catalogued as COSV99165870; called by muse, mutect2
- AGL | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV99650057; called by muse, mutect2, varscan2
- AMER1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV57669643; called by muse, mutect2
- ANAPC1 | c.1922G>A p.W641* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100594796, COSV100595103; called by muse, mutect2, varscan2
- ANO5 | c.1958G>A p.S653N | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as rs1263581083, COSV100202234, COSV61089295; called by muse, mutect2, varscan2
- ARHGAP32 | c.3103C>G p.P1035A (on ENST00000310343 / NM_001378025.1; = p.P686A on NM_014715.4) | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV100089358; called by muse, mutect2
- ARL13A | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100879050, COSV65880330; called by muse, mutect2
- AXDND1 | c.955A>C p.I319L | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100858676; called by muse, mutect2, varscan2
- BMP1 | c.2195G>C p.G732A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110150; called by muse, mutect2, varscan2
- BOD1L1 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99240449; called by muse, mutect2, varscan2
- C2 | c.922G>C p.V308L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100191496; called by muse, mutect2, varscan2
- CACNG4 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100047922, COSV50924898; called by muse, mutect2, varscan2
- CCDC92 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as COSV99435915; called by muse, mutect2
- CD244 | c.558C>A p.D186E (on ENST00000368033 / NM_001166663.2; = p.D181E on NM_016382.4) | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100458855; called by muse, mutect2, varscan2
- CEP78 | c.56A>T p.Y19F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99450943; called by muse, mutect2, varscan2
- CHL1 | c.2705C>A p.P902H (on ENST00000397491 / NM_001253387.1; = p.P918H on NM_006614.4) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56585902, COSV56595937; called by muse, mutect2, varscan2
- COLGALT2 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100730875; called by muse, mutect2, varscan2
- COQ9 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376404526; called by muse, mutect2, varscan2
- CREB5 | c.1210G>T p.E404* (on ENST00000357727 / NM_182898.4; = p.E397* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 34/137 reads (25%) | catalogued as COSV100745568, COSV63228774; called by muse, mutect2, varscan2
- CUX2 | c.4435G>A p.E1479K | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99920798; called by muse, mutect2, varscan2
- DCAF12L1 | c.942C>A p.Y314* | Nonsense Mutation (SNP) | VAF 37/178 reads (21%) | catalogued as COSV100948453; called by muse, mutect2, varscan2
- DCAF4L2 | c.244A>T p.N82Y | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV100151298; called by muse, mutect2, varscan2
- DDR1 | c.2627G>T p.C876F (on ENST00000324771; = p.C839F on NM_001954.4) | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100242122; called by muse, mutect2, varscan2
- DKK1 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100906586; called by muse, mutect2, varscan2
- DNAJC2 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99971987; called by muse, mutect2, varscan2
- DRAXIN | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99610970; called by muse, mutect2, varscan2
- DRAXIN | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs745576332, COSV99610975; called by muse, mutect2, varscan2
- DST | c.17825A>T p.H5942L (on ENST00000361203 / NM_001374722.1; = p.H3639L on NM_015548.5) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99760118; called by muse, mutect2, varscan2
- E2F7 | c.203C>G p.T68S | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100523988; called by muse, mutect2, varscan2
- FIZ1 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55607217, COSV99684747; called by muse, mutect2
- FMN2 | c.4978G>A p.A1660T | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.246); catalogued as COSV100147175; called by muse, mutect2, varscan2
- FMR1NB | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 7/119 reads (6%) | catalogued as COSV63272765; called by muse, mutect2
- GPR158 | c.3551C>A p.A1184D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as COSV100894309; called by mutect2, varscan2
- GRID2 | c.1697A>T p.D566V | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99946999; called by muse, mutect2, varscan2
- HCN1 | c.1621A>G p.I541V | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV100302397; called by muse, mutect2, varscan2
- HIP1 | c.1416G>T p.K472N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100418167; called by muse, mutect2
- HNRNPA3 | c.643+1G>T p.X215_splice | Splice Site (SNP) | VAF 12/169 reads (7%) | catalogued as COSV101182972; called by muse, mutect2
- HSPA12A | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV100979959, COSV65024047; called by muse, mutect2
- IGHV3-66 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 49/410 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.222); catalogued as rs782165547; called by muse, mutect2, varscan2
- KANK2 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100763414; called by muse, mutect2, varscan2
- KCNH5 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as COSV59769149, COSV59779760; called by muse, mutect2
- LMAN2 | c.197-2A>T p.X66_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100288496, COSV100288512; called by muse, mutect2, varscan2
- LRP10 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 32/360 reads (9%) | catalogued as COSV100612513; called by muse, mutect2
- LRP10 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV100612514; called by muse, mutect2
- LRRIQ1 | c.4834G>A p.D1612N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV101280716; called by muse, mutect2
- MAMLD1 | c.1583G>T p.S528I | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99476603; called by muse, mutect2, varscan2
- MBTPS1 | c.2897G>T p.R966L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.144); catalogued as COSV100597260, COSV100597821; called by muse, mutect2, varscan2
- MIB1 | c.2478G>T p.K826N | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.932); catalogued as COSV99839496; called by muse, mutect2
- MLST8 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs1467513600, COSV100064047; called by muse, mutect2
- MTDH | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV100292797; called by muse, mutect2, varscan2
- MTMR12 | c.1479C>A p.F493L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV99374090; called by muse, mutect2, varscan2
- MUC16 | c.7661C>A p.S2554Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV67476356, COSV67479433; called by muse, mutect2
- MUC16 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs773754733, COSV67443953; called by muse, mutect2, varscan2
- MYL2 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99960889; called by muse, mutect2, varscan2
- MYO9A | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV100614334; called by muse, mutect2, varscan2
- MYOM2 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.207); catalogued as rs375251527; called by muse, mutect2
- MYOM3 | c.708C>G p.H236Q | Missense Mutation (SNP) | VAF 101/447 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100293905; called by muse, mutect2, varscan2
- NCAM2 | c.2182C>A p.Q728K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV53097506, COSV99525349; called by muse, mutect2, varscan2
- NFASC | c.3516G>T p.Q1172H (on ENST00000339876 / NM_001378329.1; = p.Q1101H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100365740; called by muse, mutect2
- NLRP5 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs1396086410, COSV66764017; called by muse, mutect2
- NLRP7 | c.1440C>A p.Y480* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as rs201781231, COSV100052394, COSV100053391; called by muse, mutect2, varscan2
- NLRP9 | c.185A>T p.H62L | Missense Mutation (SNP) | VAF 175/681 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100243464; called by muse, mutect2, varscan2
- NPAP1 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as COSV100276214; called by muse, mutect2, varscan2
- NPAP1 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV100276216, COSV61509001; called by muse, mutect2, varscan2
- NR0B1 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV100973594; called by muse, mutect2, varscan2
- NUP210L | c.1257C>A p.Y419* | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | catalogued as COSV99669150; called by muse, mutect2
- OR13F1 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.514); catalogued as COSV100594856; called by muse, mutect2, varscan2
- OR4K5 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 63/617 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201033872, COSV100262636; called by muse, mutect2, varscan2
- OR5H6 | c.457A>T p.T153S (on ENST00000642105; = p.T137S on NM_001005479.2) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV101051818; called by muse, mutect2, varscan2
- OTOGL | c.673G>C p.V225L (on ENST00000547103; = p.V216L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV101509509; called by muse, mutect2, varscan2
- PCDH15 | c.4444G>T p.V1482L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV100227835, COSV100229083; called by muse, mutect2, varscan2
- PHLDB1 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV100616796; called by muse, mutect2, varscan2
- PLCB1 | c.3464A>G p.K1155R | Missense Mutation (SNP) | VAF 98/269 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1268524181, COSV100572211; called by muse, mutect2, varscan2
- PPP6R2 | c.2171C>T p.T724M (on ENST00000216061 / NM_001365836.1; = p.T697M on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs148549099; called by muse, mutect2, varscan2
- PTPRB | c.3371G>T p.G1124V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV99719011; called by muse, mutect2, varscan2
- PTPRD | c.2785G>C p.G929R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100647110; called by muse, mutect2
- RAB11FIP1 | c.3200C>G p.P1067R | Missense Mutation (SNP) | VAF 29/384 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as COSV99770501; called by muse, mutect2
- RAB39B | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV101035045; called by muse, mutect2
- RMDN3 | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99540274; called by muse, mutect2, varscan2
- RSRC2 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV59207327; called by muse, mutect2, varscan2
- RTL8B | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101195654; called by muse, mutect2
- RTL8B | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101195655, COSV66954618; called by muse, mutect2
- RYR2 | c.3986G>T p.G1329V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63689800; called by muse, mutect2, varscan2
- SCN2B | c.89T>C p.M30T | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV99635970; called by muse, mutect2, varscan2
- SEPTIN6 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 190/749 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV59717201; called by muse, mutect2, varscan2
- SERPINA7 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV100568489; called by muse, mutect2
- SFI1 | c.2519C>T p.A840V (on ENST00000400288 / NM_001007467.3; = p.A809V on NM_014775.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs372062054; called by muse, mutect2, varscan2
- SHPRH | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99262710; called by muse, mutect2, varscan2
- SLC15A4 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs1359878810, COSV99903809; called by muse, mutect2, varscan2
- SLC7A5 | c.1142G>T p.C381F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879507; called by muse, mutect2, varscan2
- SORT1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV99861149; called by muse, mutect2
- SPATA17 | c.1073G>C p.G358A | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV100861234; called by muse, mutect2
- SPEF2 | c.3500G>T p.R1167I | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100606155; called by muse, mutect2, varscan2
- THPO | c.1052C>A p.A351D (on ENST00000649095 / NM_001290003.1; = p.A211D on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52615440, COSV99201235; called by muse, mutect2, varscan2
- TIAM1 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs771171489, COSV99739073; called by muse, mutect2, varscan2
- TMEM185A | c.282G>T p.L94F | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100383144; called by muse, mutect2, varscan2
- TMLHE | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 11/170 reads (6%) | catalogued as COSV100545107; called by muse, mutect2
- TOP2A | c.3867G>C p.K1289N | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV101352298, COSV101352322; called by muse, mutect2, varscan2
- TRAPPC8 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1422012390, COSV99352004; called by mutect2, varscan2
- TRIM58 | c.1245G>C p.L415F | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100825305, COSV63571664; called by muse, mutect2, varscan2
- TRIP6 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566908; called by muse, mutect2, varscan2
- TRPC5 | c.1773A>T p.K591N | Missense Mutation (SNP) | VAF 57/664 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.643); catalogued as COSV99462789; called by muse, mutect2
- TSPAN14 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV99627937; called by muse, varscan2
- TTN | c.25513G>A p.A8505T (on ENST00000591111; = p.A7578T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/225 reads (10%) | PolyPhen benign (0.053); catalogued as rs184883436, COSV100628801; ClinVar: not provided; called by muse, mutect2
- U2AF2 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100454466; called by muse, mutect2
- UBQLN4 | c.233T>A p.V78D | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100849121; called by muse, mutect2, varscan2
- UNC79 | c.1776G>T p.K592N (on ENST00000393151 / NM_001346218.2; = p.K415N on NM_020818.5) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV99829885; called by muse, mutect2, varscan2
- ZFHX4 | c.7546T>A p.F2516I | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.399); catalogued as COSV50701731, COSV99267824; called by muse, mutect2
- ZFHX4 | c.8497G>C p.V2833L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.176); catalogued as rs1466220995, COSV99267827; called by muse, mutect2, varscan2
- ZMYND12 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs773861975, COSV100999907; called by muse, mutect2, varscan2
- ZNF492 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV71761986, COSV71762282; called by muse, mutect2, varscan2
- ARMC9 | c.1626+1del | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- MIDEAS | c.2893del p.A965Qfs*128 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1991A>G p.E664G | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.08); called by muse, mutect2
- SYNJ1 | c.3899_3904del p.Q1300_E1301del | In Frame Del (DEL) | VAF 22/246 reads (9%) | called by mutect2, pindel
- ACP5 | c.477A>T p.T159= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99520536; called by muse, mutect2
- AFF2 | c.1392T>A p.P464= | Silent (SNP) | VAF 12/197 reads (6%) | catalogued as COSV99666342; called by muse, mutect2
- CAPN10 | c.969G>A p.E323= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as COSV54376627, COSV99550551; called by muse, mutect2, varscan2
- CD244 | c.702C>A p.I234= (on ENST00000368033 / NM_001166663.2; = p.I229= on NM_016382.4) | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100458851, COSV59238640; called by muse, mutect2, varscan2
- CHST6 | c.984C>T p.N328= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as rs112748405; called by muse, mutect2, varscan2
- COL24A1 | c.2991G>T p.L997= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100994001; called by muse, mutect2, varscan2
- DCUN1D4 | c.798C>T p.L266= (on ENST00000334635 / NM_001287757.1; = p.L231= on NM_015115.3) | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV58121561; called by muse, mutect2, varscan2
- DPYD | c.1521A>T p.V507= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs373838132, COSV64597809; called by muse, varscan2
- ENOX2 | c.1803C>T p.F601= (on ENST00000338144 / NM_001382520.1; = p.F572= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV100584606; called by muse, mutect2, varscan2
- FRAS1 | c.4443G>T p.L1481= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV99355896; called by muse, mutect2, varscan2
- IGHV3-35 | c.321C>T p.A107= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as rs1303760689; called by muse, mutect2
- KMT2D | c.5835A>T p.P1945= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99985896; called by muse, mutect2, varscan2
- KRTAP10-6 | c.927C>T p.H309= | Silent (SNP) | VAF 54/253 reads (21%) | catalogued as rs182188411, COSV100555535; called by muse, mutect2, varscan2
- LMTK2 | c.2211C>T p.S737= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52002889; called by muse, mutect2, varscan2
- LRRK1 | c.5865G>T p.P1955= | Silent (SNP) | VAF 51/188 reads (27%) | catalogued as COSV99443236; called by muse, mutect2, varscan2
- MS4A10 | c.375G>T p.L125= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as COSV100382444, COSV57632872; called by muse, mutect2, varscan2
- NKD1 | c.387C>A p.S129= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as COSV51693414, COSV99194137; called by muse, mutect2, varscan2
- NOMO1 | c.3354C>A p.L1118= | Silent (SNP) | VAF 56/792 reads (7%) | catalogued as rs778567003, COSV99814890; called by muse, mutect2
- OR5D16 | c.756C>A p.I252= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as COSV101004147; called by muse, mutect2, varscan2
- OR5M8 | c.396C>A p.G132= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV100510784; called by muse, mutect2
- PCDHA13 | c.201G>A p.A67= | Silent (SNP) | VAF 60/296 reads (20%) | catalogued as rs1211271964, COSV56505850; called by muse, mutect2, varscan2
- PEG3 | c.417C>A p.T139= | Silent (SNP) | VAF 27/152 reads (18%) | catalogued as COSV99690421; called by muse, mutect2, varscan2
- PLXNA1 | c.4185G>T p.T1395= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1021917643, COSV99304126; called by muse, mutect2, varscan2
- PRDM14 | c.1035A>G p.Q345= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV99400527; called by muse, mutect2, varscan2
- PTPRB | c.3372G>T p.G1124= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99719006; called by muse, mutect2, varscan2
- RASGRF1 | c.885C>A p.T295= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV101369757; called by mutect2, varscan2
- RBMXL1 | c.1077A>T p.S359= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as COSV99556997; called by muse, mutect2, varscan2
- SARNP | c.24C>T p.L8= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as rs539265542, COSV99670865; called by muse, mutect2, varscan2
- SHQ1 | c.36G>T p.P12= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV100345378; called by muse, mutect2, varscan2
- SLITRK5 | c.1782G>A p.A594= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV61522055; called by muse, mutect2
- THSD7A | c.3702G>C p.L1234= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV69856352; called by muse, mutect2, varscan2
- TNN | c.3120C>T p.S1040= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV53435299; called by muse, mutect2, varscan2
- WASHC4 | c.2121G>T p.L707= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV100162777; called by muse, mutect2
- AC073310.1 | n.368C>A | RNA (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- AC073310.1 | n.369C>A | RNA (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
